Somatic mutation profile of tumor specimen 0DG87V from CCDI case PBBTCV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebrum; Age at diagnosis: 8.9 years (3,266 days).
Specimen 0DG87V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0be887d-2aa5-42b3-83cd-7b2e84574c2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG84J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/250cc2c8-5591-4bae-9999-ce122667dff3

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 361/1081 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASTN1 | c.2211G>T p.K737N | Missense Mutation (SNP) | VAF 483/1152 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV56060462, COSV99923621; called by muse, mutect2, varscan2
- FXR2 | c.1619dup p.A541Sfs*14 | Frame Shift Ins (INS) | VAF 242/340 reads (71%) | catalogued as rs753982098; called by mutect2, varscan2
- IRF2 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 395/1111 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs1249195947; called by muse, mutect2, varscan2
- RNF123 | c.2821C>T p.R941* | Nonsense Mutation (SNP) | VAF 215/563 reads (38%) | catalogued as rs1372546460; called by muse, mutect2, varscan2
- ATXN7L1 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 51/946 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- CEP20 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 268/736 reads (36%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPC1 | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 275/795 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GPR152 | c.755C>G p.P252R | Missense Mutation (SNP) | VAF 151/361 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HSD17B1 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 362/833 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2G3 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 129/914 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RBM46 | c.1288_1291del p.I430Lfs*22 | Frame Shift Del (DEL) | VAF 348/802 reads (43%) | called by mutect2, varscan2
- MALSU1 | c.111G>C p.L37= | Silent (SNP) | VAF 128/2898 reads (4%) | called by muse, mutect2
- RXFP3 | c.714G>A p.T238= | Silent (SNP) | VAF 50/630 reads (8%) | catalogued as rs547132118, COSV57508081; called by muse, mutect2
- YME1L1 | c.972T>G p.L324= (on ENST00000326799 / NM_139312.3; = p.L267= on NM_014263.4) | Silent (SNP) | VAF 42/1198 reads (4%) | called by muse, mutect2
